CCDI case PBCNTA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/af43792e-e86f-4d17-ae3f-be53d5d8771b

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (65 days).

Biospecimens (3 samples)
- Sample 0DWERQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWERZ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWES8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
